Gene-level copy-number profile of tumor specimen C3L-06219-05 from CPTAC case C3L-06219, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 67.0 years (24,463 days).
Specimen C3L-06219-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9659dde1-2133-45f9-96c7-ab5368d641d3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06219-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/05c97bf9-c9cf-4a2d-8d06-630027db9bd4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 419; copy number 1: 4,654; copy number 2: 44,809; copy number 3: 8,202; copy number 4: 226; copy number 5: 395; copy number 6: 183; copy number 10: 7; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:25,809,925–25,810,656, 1 gene (within-gene range 0–1): TPM3P7.
- chr2:241,227,264–241,637,158, 14 genes (within-gene range 0–1): HDLBP, SEPTIN2, AC104841.1, AC005104.1, FARP2, AC005104.2, MIR3133, KCTD5P1, STK25, BOK-AS1, BOK, AC133528.1, THAP4, RNA5SP122.
- chr3:4,414,580–4,493,163, 2 genes (within-gene range 0–1): MRPS10P2, ITPR1-DT.
- chr6:1,623,806–2,245,605, 2 genes: GMDS, AL035693.1.
- chr6:126,340,115–126,348,875, 1 gene: CENPW.
- chr7:7,550,104–7,566,996, 2 genes (within-gene range 0–2): AC004982.1, AC004982.2.
- chr7:18,429,062–18,430,738, 1 gene (within-gene range 0–1): AC010082.1.
- chr7:105,013,425–105,115,019, 3 genes (within-gene range 0–1): KMT2E-AS1, KMT2E, AC005070.3.
- chr11:2,444,684–2,849,105, 7 genes (within-gene range 0–1): KCNQ1, KCNQ1OT1, AC021424.1, AC021424.3, AC021424.4, AC021424.2, COX6CP18.
- chr12:111,753,890–111,817,532, 3 genes (within-gene range 0–1): AC002996.1, ALDH2, MIR6761.
- chr12:118,063,593–118,145,584, 3 genes (within-gene range 0–2): VSIG10, AC131238.1, PEBP1.
- chr15:57,246,960–57,278,673, 2 genes (within-gene range 0–1): HNRNPA3P11, SNORD13D.
- chr15:59,132,434–59,372,871, 7 genes (within-gene range 0–1): MYO1E, MIR2116, LDHAL6B, RNU4-80P, AC092756.1, RNU6-212P, AC092868.2.
- chr15:71,341,158–71,549,832, 2 genes (within-gene range 0–1): AC064799.1, AC108861.1.
- chr17:58,324,472–58,415,766, 1 gene (within-gene range 0–2): TSPOAP1-AS1.
- chr17:58,335,976–58,417,595, 4 genes (within-gene range 0–2): MIR4736, SUPT4H1, AC004687.2, RNF43.
- chr18:49,013,106–49,048,474, 2 genes (within-gene range 0–1): AC016866.3, AC016866.1.
- chr18:49,049,687–49,049,768, 1 gene (within-gene range 0–1): MIR4744.
- chr18:49,795,793–50,195,147, 11 genes (within-gene range 0–1): AC090227.2, SNHG22, SCARNA17, AC090227.1, MYO5B, Y_RNA, RNA5SP457, AC091044.1, ADAD1P2, AC105224.1, MIR4320.
- chr18:62,715,541–62,980,433, 2 genes (within-gene range 0–1): PHLPP1, RNU6-142P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 577 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,589,494–91,621,421, 1 gene, copy number 5 (within-gene range 4–5): AC116050.1.
- chr6:3,941,282–4,189,806, 13 genes, copy number 5: TDGF1P4, GLRX3P2, AL138831.3, AL138831.2, AL138831.1, PRPF4B, FAM217A, C6orf201, ECI2, AL136309.3, ECI2-DT, AL136309.2, AL136309.1.
- chr8:5,072,645–18,027,975, 337 genes, copy number 5 (broad region; genes not listed).
- chr9:67,832,765–68,540,883, 13 genes, copy number 5: ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252.
- chr13:73,054,976–73,661,891, 9 genes, copy number 5: KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr14:18,333,726–18,650,966, 17 genes, copy number 6–12: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr16:46,469,341–46,698,394, 12 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6.
- chr17:36,253,456–36,543,435, 11 genes, copy number 6 (within-gene range 2–6): TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, TBC1D3F, TBC1D3J, ZNHIT3, RNA5SP439, MYO19, PIGW.
- chr17:38,297,023–41,140,487, 153 genes, copy number 6 (broad region; genes not listed).
- chr21:10,482,738–13,120,807, 11 genes, copy number 6–10 (within-gene range 3–10): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 2,191. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
